Somatic mutation profile of tumor specimen TARGET-10-PASKRN-03A (aliquot TARGET-10-PASKRN-03A-01D) from TARGET case TARGET-10-PASKRN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,895 days).
Specimen TARGET-10-PASKRN-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e4edf92-c94d-4017-9ddb-9a8a314b6017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASKRN-10A (Blood Derived Normal), aliquot TARGET-10-PASKRN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7362f699-b1cd-4dcc-ab10-e8fe20d5014c

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Ins 1, Splice Site 1, Intron 1, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1700C>T p.P567L (on ENST00000399959; = p.P568L on NM_001356.5) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519430, CM158051, COSV67863241; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ESRP1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV64412165; called by muse, mutect2, varscan2
- LAMB4 | c.3917-1G>T p.X1306_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV52728775; called by mutect2, varscan2
- LEF1 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1359509909, COSV54465851; called by muse, mutect2, varscan2
- MUC16 | c.1951G>A p.V651M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs373974302, COSV67487849; called by mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- ZFHX4 | c.2855C>T p.T952I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51449897, COSV51490383; called by muse, mutect2, varscan2
- COG1 | c.1682C>A p.A561E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); called by muse, mutect2
- FAM126B | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- RPL5 | c.242_243insG p.H81Qfs*32 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | called by mutect2, varscan2
- UTP20 | c.5926C>A p.Q1976K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LRP1 | c.225C>T p.N75= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs148631104; called by muse, mutect2, varscan2
- NACA | c.71-1741_71-1740insAC | Intron (INS) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- SNORD113-6 | chr14:100939633 C>A | 3'Flank (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
